Somatic mutation profile of tumor specimen 0DVPOV from CCDI case PBCMYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,446 days).
Specimen 0DVPOV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c5fe58b-7086-4f76-a0e2-7b8c273825ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4b6bc52-f099-4a75-842f-009d1c6c9650

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 2, Splice Site 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPZA2 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 256/588 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1562954696; called by muse, mutect2, varscan2
- KRT2 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 267/579 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.394); catalogued as rs1247684905, COSV59009057, COSV59012504; called by muse, mutect2, varscan2
- LRP1B | c.3134A>G p.E1045G | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67266419; called by muse, mutect2
- NLRP8 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 41/577 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as rs201462125; called by muse, mutect2
- PCDHA5 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 262/773 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65354508; called by muse, mutect2, varscan2
- PCDHGA10 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 60/1204 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs749121255, COSV53945509; called by muse, mutect2
- ZNF493 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100828827; called by muse, mutect2, varscan2
- FAM117B | c.1449C>T p.C483= | Splice Region (SNP) | VAF 200/497 reads (40%) | called by muse, mutect2, varscan2
- IFFO1 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 38/737 reads (5%) | called by muse, mutect2
- NFYC | c.721-1G>T p.X241_splice | Splice Site (SNP) | VAF 126/240 reads (53%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 20/639 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZFP82 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 51/496 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHADL | c.960C>A p.P320= | Silent (SNP) | VAF 29/397 reads (7%) | called by muse, mutect2
- MAST3 | c.33G>A p.G11= | Silent (SNP) | VAF 26/463 reads (6%) | called by muse, mutect2
- RHBG | c.1161G>A p.T387= | Silent (SNP) | VAF 45/594 reads (8%) | catalogued as rs375029436; called by muse, mutect2
- SDR39U1 | c.354G>A p.A118= | Silent (SNP) | VAF 142/411 reads (35%) | catalogued as rs1002782740, COSV52163855, COSV99249457; called by muse, mutect2, varscan2
- AP2A2 | c.2421-24_2421-21del | Intron (DEL) | VAF 153/430 reads (36%) | called by mutect2, pindel, varscan2
- NPAP1L | n.350A>G | RNA (SNP) | VAF 14/460 reads (3%) | called by muse, mutect2
- RXYLT1 | c.169+75C>T | Intron (SNP) | VAF 98/206 reads (48%) | catalogued as rs1215553415; called by muse, mutect2, varscan2
